Surgical pathology report (de-identified scan), TCGA case TCGA-BR-8297, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Asterand, specimen TCGA-BR-8297-01A (Primary Tumor).

[page 1 of 6]
		Case ID	Gross Description

[page 2 of 6]
Microscopic Description	Diagnosis Details

[page 3 of 6]
Comments	Formatted Path Report
	STOMACH TISSUE CHECKLIST Specimen type: Gastrectomy Tumor site: Fundus Tumor size: 31 x 15 x 2 cm Tumor features: Ulcerated, Diffusely infiltrating (linitus plastica) Histologic type: Adenocarcinoma, diffuse type Histologic grade: Not specified Tumor extent: Adjacent structures (specify) - Esophagus Lymph nodes: 11/11 positive for metastasis (Intraabdominal 11/11) Lymphatic invasion: Not specified Venous invasion: Not specified Perineural invasion: Not specified Margins: Involved Evidence of neo-adjuvant treatment: Not specified Additional pathologic findings: Not specified Comments: None

[page 4 of 6]
Laterality		ID

[page 5 of 6]
Excision date		Case ID	

Source: NCI Genomic Data Commons file a2e8d710-9cbe-404d-a1c3-4c5c1b02f359 (TCGA-BR-8297.9FC14CF7-D917-47B0-94F3-1532301B5EEF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).